Somatic mutation profile of tumor specimen TARGET-40-0A4I0Q-01A (aliquot TARGET-40-0A4I0Q-01A-01D) from TARGET case TARGET-40-0A4I0Q, project TARGET-OS (Osteosarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 19.9 years (7,269 days).
Specimen TARGET-40-0A4I0Q-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e81f608e-5b0e-40d1-b8fc-adb60cdaf84f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-40-0A4I0Q-10A (Blood Derived Normal), aliquot TARGET-40-0A4I0Q-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/513c9053-f5e8-4ee1-8a7c-fbf747bf88e5

The open-access MAF lists 17 somatic variants for this specimen: 12 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 3, Intron 1, Splice Site 1, RNA 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IARS1 | c.1505+1G>T p.X502_splice | Splice Site (SNP) | VAF 5/25 reads (20%) | catalogued as rs1240010127; called by muse, mutect2, varscan2
- IGSF9B | c.2623G>A p.E875K | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as rs932943837, COSV58065212; called by muse, mutect2, varscan2
- STAB2 | c.3428G>A p.R1143Q | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.994); catalogued as rs182960938, COSV101185592; called by muse, mutect2, varscan2
- TENM4 | c.8153G>A p.R2718Q | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs373894701; called by muse, mutect2, varscan2
- COQ6 | c.1010G>C p.R337T | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT tolerated (0.31); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CXXC1 | c.1827G>A p.W609* | Nonsense Mutation (SNP) | VAF 45/77 reads (58%) | called by muse, mutect2, varscan2
- HASPIN | c.970G>T p.V324L | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT tolerated (0.19); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ITGA1 | c.1649G>A p.C550Y | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.17); called by muse, mutect2, varscan2
- LCE2B | c.113C>A p.A38D | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.979); called by muse, mutect2
- MAP3K21 | c.2816T>A p.V939D | Missense Mutation (SNP) | VAF 35/78 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- TONSL | c.1624C>G p.L542V | Missense Mutation (SNP) | VAF 26/117 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.721); called by muse, mutect2, varscan2
- USP6NL | c.580G>A p.A194T | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); called by muse, mutect2
- CFAP54 | c.6147T>C p.T2049= | Silent (SNP) | VAF 25/67 reads (37%) | called by muse, mutect2, varscan2
- COL9A1 | c.1137A>G p.G379= | Silent (SNP) | VAF 16/41 reads (39%) | called by muse, mutect2, varscan2
- KDM5B | c.3024G>A p.A1008= | Silent (SNP) | VAF 13/28 reads (46%) | catalogued as rs745340526; called by muse, mutect2, varscan2
- DNAJC6 | c.22+44842dup | Intron (INS) | VAF 34/100 reads (34%) | called by mutect2, pindel, varscan2
- OR8V1P | n.164C>A | RNA (SNP) | VAF 10/45 reads (22%) | called by muse, mutect2, varscan2
